Surgical pathology report (de-identified scan), TCGA case TCGA-G2-A2EL, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site MD Anderson, specimen TCGA-G2-A2EL-01A (Primary Tumor).

PATHOLOGY REPORT

1CD-0-3

Carcinoma, urothelial, NOS 8120/3

Site: bladder, wall, lateral C67.2

hw
6/23/11

DIAGNOSIS

(A) BLADDER TUMOR, LEFT LATERAL WALL:

UROTHELIAL CARCINOMA, HIGH GRADE, WITH EXTENSIVE SMALL CELL DIFFERENTIATION.

TUMOR IS INVASIVE INTO MUSCULARIS PROPRIA.

POSITIVE FOR LYMPHOVASCULAR INVASION.

CONSULTANT(S)

GROSS DESCRIPTION

(A) BLADDER TUMOR LEFT LATERAL WALL - Multiple pale gray tissue fragments (3.0 x 2.8 x 0.9 cm in aggregate). Entirely submitted in A1 and A2.

CLINICAL HISTORY

Bladder carcinoma.

hw 6/23/11

Source: NCI Genomic Data Commons file 2800fc7b-c9b5-4e65-a7b5-7c2a9dd79e3f (TCGA-G2-A2EL.E021F112-7358-4CD0-870A-A29D0115CAE3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).